Somatic mutation profile of tumor specimen TCGA-BP-4163-01A (aliquot TCGA-BP-4163-01A-02D-1386-10) from TCGA case TCGA-BP-4163, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 60.2 years (21,980 days).
Specimen TCGA-BP-4163-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fcb9d7ac-33cf-40d9-8bf2-14567cf5d4c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4163-11A (Solid Tissue Normal), aliquot TCGA-BP-4163-11A-01D-1251-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/83557c0f-99bf-4809-a4fb-9fe38c02520f

The open-access MAF lists 44 somatic variants for this specimen: 33 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 28, Silent 11, Nonsense Mutation 2, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASPM | c.9549G>C p.R3183S | Missense Mutation (SNP) | VAF 115/483 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.739); catalogued as COSV54132380; called by muse, mutect2, varscan2
- BAP1 | c.836C>A p.S279* | Nonsense Mutation (SNP) | VAF 21/56 reads (38%) | catalogued as COSV56236202, COSV56242210; called by muse, mutect2, varscan2
- BCAS2 | c.136A>C p.T46P | Missense Mutation (SNP) | VAF 126/505 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.816); catalogued as COSV65767475; called by muse, mutect2, varscan2
- CCDC47 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 54/196 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV56723410; called by muse, mutect2, varscan2
- CENPE | c.5744C>T p.T1915I | Missense Mutation (SNP) | VAF 122/605 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.075); catalogued as COSV54383093; called by muse, mutect2, varscan2
- DNAJC17 | c.725T>A p.L242Q | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55025424; called by muse, mutect2, varscan2
- IFI30 | c.335G>C p.R112T | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as rs1455216431, COSV55848653; called by muse, mutect2
- IVD | c.851A>T p.D284V (on ENST00000651168; = p.D281V on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV51099668; called by muse, mutect2, varscan2
- KDM4A | c.1935G>C p.Q645H | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64959965; called by muse, mutect2, varscan2
- LAMB4 | c.2027T>A p.I676N | Missense Mutation (SNP) | VAF 115/418 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs1349859087, COSV52722292; called by muse, mutect2, varscan2
- MRPL9 | c.742T>A p.Y248N | Missense Mutation (SNP) | VAF 71/260 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as COSV58618495; called by muse, mutect2, varscan2
- MRPS7 | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as COSV55453714; called by muse, mutect2, varscan2
- NIPBL | c.5354C>G p.A1785G | Missense Mutation (SNP) | VAF 182/714 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV56955674; called by muse, mutect2, varscan2
- OR56A4 | c.443G>C p.S148T | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.073); catalogued as COSV58110594; called by muse, mutect2, varscan2
- OTOL1 | c.916C>A p.P306T | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.472); catalogued as COSV60007157; called by muse, mutect2, varscan2
- PKD2L2 | c.232T>G p.F78V | Missense Mutation (SNP) | VAF 122/566 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV51798813; called by muse, mutect2
- PSMA3 | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 167/522 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.146); catalogued as COSV53617505; called by muse, mutect2, varscan2
- RAB8B | c.614C>T p.S205L | Missense Mutation (SNP) | VAF 57/218 reads (26%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs373850007, COSV58489708; called by muse, mutect2, varscan2
- RARA | c.610C>A p.Q204K | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV54193439; called by muse, mutect2, varscan2
- SHARPIN | c.390C>G p.N130K | Missense Mutation (SNP) | VAF 114/527 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV59363351; called by muse, mutect2, varscan2
- SLC25A45 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV53684203; called by muse, mutect2, varscan2
- STEAP1 | c.257T>C p.F86S | Missense Mutation (SNP) | VAF 113/452 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV51882061; called by mutect2, varscan2
- TEX264 | c.26T>A p.L9Q | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58134754; called by muse, varscan2
- TNS2 | c.535T>G p.S179A (on ENST00000314250 / NM_170754.4; = p.S189A on NM_015319.2) | Missense Mutation (SNP) | VAF 168/380 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV58578679; called by muse, mutect2, varscan2
- TOPBP1 | c.2009T>A p.L670H | Missense Mutation (SNP) | VAF 84/214 reads (39%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV53437428; called by muse, mutect2, varscan2
- TSC22D4 | c.970C>A p.Q324K | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV55724512; called by muse, varscan2
- WDR35 | c.1376A>G p.K459R (on ENST00000345530 / NM_001006657.2; = p.K448R on NM_020779.4) | Missense Mutation (SNP) | VAF 145/648 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV55604090; called by muse, mutect2, varscan2
- ZIK1 | c.669A>C p.K223N | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as COSV56737522; called by muse, mutect2, varscan2
- CIDEC | c.570G>T p.W190C | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.088); called by muse, mutect2
- G6PC | c.626dup p.Y209* | Nonsense Mutation (INS) | VAF 24/124 reads (19%) | called by mutect2, pindel, varscan2
- MYCBP2 | c.7549_7552del p.S2517Kfs*11 (on ENST00000357337; = p.S2555Kfs*11 on NM_015057.5) | Frame Shift Del (DEL) | VAF 16/94 reads (17%) | called by mutect2, pindel
- NELFCD | c.1283_1283+3del p.X428_splice (on ENST00000602795; = p.X410_splice on NM_198976.4) | Splice Site (DEL) | VAF 65/305 reads (21%) | called by mutect2, pindel, varscan2
- THAP6 | c.57_60del p.L20Kfs*3 | Frame Shift Del (DEL) | VAF 100/502 reads (20%) | called by mutect2, pindel, varscan2
- ATP13A4 | c.3549T>C p.S1183= | Silent (SNP) | VAF 26/312 reads (8%) | catalogued as COSV61321448; called by muse, mutect2
- DNAH17 | c.5634C>T p.D1878= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV67757074; called by muse, mutect2, varscan2
- EMC3 | c.717A>G p.E239= | Silent (SNP) | VAF 69/277 reads (25%) | catalogued as COSV55278629; called by muse, mutect2, varscan2
- FAT3 | c.10854G>T p.L3618= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as COSV53129232; called by muse, mutect2, varscan2
- HEATR3 | c.1497T>G p.L499= | Silent (SNP) | VAF 27/147 reads (18%) | catalogued as COSV53529928; called by muse, mutect2, varscan2
- LRRK1 | c.4761G>A p.Q1587= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as COSV52616145; called by muse, mutect2, varscan2
- MLX | c.624A>G p.L208= | Silent (SNP) | VAF 86/365 reads (24%) | catalogued as rs757128415, COSV53817653; called by muse, mutect2, varscan2
- MPV17L | c.441A>G p.Q147= (on ENST00000396385 / NM_001128423.2; = p.M124V on NM_173803.4) | Silent (SNP) | VAF 172/500 reads (34%) | catalogued as rs756473622, COSV55008662; called by muse, mutect2, varscan2
- PCNX1 | c.6114A>T p.G2038= | Silent (SNP) | VAF 63/242 reads (26%) | catalogued as COSV53096631; called by muse, mutect2, varscan2
- PLS3 | c.444A>G p.P148= | Silent (SNP) | VAF 164/509 reads (32%) | catalogued as COSV56779600; called by muse, mutect2, varscan2
- SULT2B1 | c.627C>G p.T209= (on ENST00000201586 / NM_177973.2; = p.T194= on NM_004605.2) | Silent (SNP) | VAF 19/134 reads (14%) | catalogued as COSV52376837; called by muse, mutect2
